Somatic mutation profile of tumor specimen TCGA-61-2096-01A (aliquot TCGA-61-2096-01A-01W-0722-08) from TCGA case TCGA-61-2096, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G2; Age at diagnosis: 56.6 years (20,663 days).
Specimen TCGA-61-2096-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa9c9c74-bf43-48f3-8750-337a2d38fe8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2096-11A (Solid Tissue Normal), aliquot TCGA-61-2096-11A-01W-0723-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49368abe-5efe-4577-9c21-62469e144f20

The open-access MAF lists 120 somatic variants for this specimen: 95 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 22, Splice Site 4, Nonsense Mutation 3, Frame Shift Del 3, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 94/118 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic; called by muse, varscan2
- ABCC12 | c.3494T>C p.M1165T | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs759060031, COSV100252232; called by muse, mutect2, varscan2
- ACSS1 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.142); catalogued as COSV100053447; called by muse, mutect2, varscan2
- ADGRV1 | c.6253G>A p.A2085T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101315545; called by muse, mutect2, varscan2
- AFAP1L2 | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs774263438, COSV58415168; called by muse, mutect2, varscan2
- ALDOB | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 64/728 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as COSV100878817; called by muse, mutect2
- ALS2 | c.2648G>C p.G883A | Missense Mutation (SNP) | VAF 156/279 reads (56%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV99968857; called by muse, mutect2, varscan2
- APC | c.4204G>A p.A1402T | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57342267, COSV57391917; called by muse, mutect2, varscan2
- APC | c.4205C>T p.A1402V | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57382763; called by muse, mutect2, varscan2
- AXDND1 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100858261; called by muse, mutect2, varscan2
- BDP1 | c.3036G>C p.L1012F | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100702775; called by muse, mutect2, varscan2
- BIRC3 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 14/478 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99679725; called by muse, mutect2
- BOC | c.173T>G p.V58G | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as COSV99848225; called by muse, mutect2, varscan2
- BPI | c.676+1G>T p.X226_splice (on ENST00000262865; = p.X222_splice on NM_001725.3) | Splice Site (SNP) | VAF 74/147 reads (50%) | catalogued as COSV99480437; called by muse, mutect2, varscan2
- BRCA1 | c.5510G>T p.W1837L | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960191, COSV100523420; called by muse, mutect2, varscan2
- CACNA1C | c.1031C>T p.T344I | Missense Mutation (SNP) | VAF 396/796 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs200935321, COSV100216006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMTA1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs1302737834, COSV57881226; called by muse, mutect2, varscan2
- CAMTA2 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 71/89 reads (80%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); catalogued as COSV100741998; called by muse, mutect2, varscan2
- CC2D1A | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.824); catalogued as COSV100528294; called by muse, mutect2
- CNKSR3 | c.476T>A p.L159H | Missense Mutation (SNP) | VAF 203/232 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101527225; called by muse, mutect2, varscan2
- COL6A3 | c.4852G>A p.A1618T | Missense Mutation (SNP) | VAF 166/312 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as COSV99796415; called by muse, mutect2, varscan2
- CSMD2 | c.8917A>G p.T2973A | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.728); catalogued as COSV99586742; called by muse, mutect2, varscan2
- DCAF1 | c.3565C>A p.Q1189K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100244135; called by muse, mutect2, varscan2
- DNASE2 | c.925G>C p.V309L | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV52246608, COSV99262413, COSV99263955; called by muse, mutect2, varscan2
- DNHD1 | c.1388G>C p.R463P | Missense Mutation (SNP) | VAF 151/178 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV99599522; called by muse, mutect2, varscan2
- DOCK1 | c.1800C>G p.D600E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99727220; called by muse, mutect2, varscan2
- EIF6 | c.116A>T p.E39V | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100981522; called by muse, mutect2, varscan2
- ESYT1 | c.1711A>G p.I571V | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1003017466, COSV99919735; called by muse, mutect2, varscan2
- F2 | c.1299-1G>T p.X433_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100319363, COSV61315727; called by muse, mutect2, varscan2
- F2RL2 | c.1022T>A p.L341H | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99166758; called by muse, mutect2, varscan2
- FAM13A | c.2684A>C p.K895T | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV99982958; called by muse, mutect2, varscan2
- FAM167A | c.502A>T p.T168S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as COSV99452981; called by muse, mutect2, varscan2
- FBN2 | c.4373A>C p.N1458T | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.82); catalogued as COSV99325418; called by muse, mutect2, varscan2
- FCGR2A | c.769G>T p.A257S (on ENST00000271450 / NM_001136219.3; = p.A256S on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 359/1488 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as COSV99615043; called by muse, mutect2, varscan2
- FOXP2 | c.1195C>A p.R399S | Missense Mutation (SNP) | VAF 140/158 reads (89%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.953); catalogued as COSV100646314, COSV63482676; called by muse, mutect2, varscan2
- FRAS1 | c.4204A>T p.T1402S | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99348781; called by muse, mutect2, varscan2
- GHR | c.709T>A p.S237T | Missense Mutation (SNP) | VAF 297/600 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100049982; called by muse, mutect2, varscan2
- H2BC21 | c.14C>G p.A5G | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs1056149453, COSV100479711; called by muse, mutect2, varscan2
- HLA-DMA | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV100877657; called by muse, mutect2, varscan2
- HLTF | c.2294A>G p.D765G | Missense Mutation (SNP) | VAF 26/616 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100026734; called by muse, mutect2
- ITPRIP | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 73/91 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1291443960, COSV99532419; called by muse, mutect2, varscan2
- KCTD10 | c.502A>T p.S168C | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.848); catalogued as COSV99949065; called by muse, mutect2
- KIAA1549L | c.5438C>T p.P1813L (on ENST00000321505; = p.P2110L on NM_012194.3) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs368885129, COSV58591971; called by muse, mutect2, varscan2
- KRT17 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100245063; called by muse, mutect2, varscan2
- KRTAP10-5 | c.478C>G p.P160A | Missense Mutation (SNP) | VAF 286/754 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100552135; called by muse, mutect2, varscan2
- LRMDA | c.152C>A p.T51N | Missense Mutation (SNP) | VAF 95/150 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100994428; called by muse, mutect2, varscan2
- LRRK1 | c.2399A>C p.H800P | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV99438001; called by muse, mutect2, varscan2
- MACF1 | c.19462G>C p.E6488Q (on ENST00000372915; = p.E4533Q on NM_012090.5) | Missense Mutation (SNP) | VAF 114/265 reads (43%) | catalogued as COSV99241755; called by muse, mutect2, varscan2
- MYOM3 | c.4301T>G p.L1434R | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV100141563; called by muse, mutect2, varscan2
- NCOA2 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs748237390, COSV71763312; called by muse, mutect2
- NECAB2 | c.1135G>C p.A379P | Missense Mutation (SNP) | VAF 141/345 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs768431015, COSV100533849, COSV59421259; called by muse, mutect2, varscan2
- NPHP1 | c.843G>C p.E281D | Missense Mutation (SNP) | VAF 26/641 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.952); catalogued as COSV100337836; called by muse, mutect2
- NRDC | c.2639T>A p.L880* | Nonsense Mutation (SNP) | VAF 14/446 reads (3%) | catalogued as COSV100703140; called by muse, mutect2
- OGT | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV101035195; called by muse, mutect2
- OR4C11 | c.622A>T p.S208C | Missense Mutation (SNP) | VAF 128/314 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100155226; called by muse, varscan2
- PAK5 | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 576/1413 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs756676424, COSV100781141, COSV100781636; called by muse, mutect2, varscan2
- PCDH17 | c.1933A>G p.I645V | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV100931459; called by muse, mutect2, varscan2
- PLB1 | c.4145G>A p.S1382N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV100577764; called by muse, mutect2
- PML | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs61751125; called by muse, mutect2
- PPP1R3A | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 204/219 reads (93%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369167258; called by muse, mutect2, varscan2
- PRRC2C | c.2783C>G p.S928C (on ENST00000367742; = p.S926C on NM_015172.4) | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs775022901, COSV100144757, COSV58906232; called by muse, mutect2, varscan2
- PSMC2 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 231/495 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99485174; called by muse, mutect2, varscan2
- PTPRC | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 265/899 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV61412107, COSV61422978; called by muse, mutect2, varscan2
- PXDNL | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs766523476, COSV62485333, COSV62485839; called by muse, mutect2, varscan2
- RFPL1 | c.197C>A p.S66* | Nonsense Mutation (SNP) | VAF 139/171 reads (81%) | catalogued as COSV100585653; called by muse, mutect2, varscan2
- SAP30L | c.365A>C p.Y122S | Missense Mutation (SNP) | VAF 104/169 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99770355; called by muse, mutect2, varscan2
- SCYL1 | c.1856C>A p.P619H | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV99533828; called by muse, mutect2, varscan2
- SGIP1 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs775231208, COSV52774322, COSV99390650; called by muse, mutect2, varscan2
- SH2D5 | c.754G>A p.G252S (on ENST00000444387 / NM_001103161.2; = p.G168S on NM_001103160.2) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs770547680, COSV100903794; called by mutect2, varscan2
- SLC5A1 | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 169/212 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV56684180, COSV99833228; called by muse, mutect2, varscan2
- SMC5 | c.783T>G p.D261E | Missense Mutation (SNP) | VAF 290/333 reads (87%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV100746984; called by muse, mutect2, varscan2
- SPHKAP | c.2371A>C p.M791L | Missense Mutation (SNP) | VAF 208/518 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100763764; called by muse, mutect2, varscan2
- STAG1 | c.3505G>A p.D1169N | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV99364593; called by muse, mutect2
- STXBP5L | c.876T>G p.H292Q | Missense Mutation (SNP) | VAF 167/426 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99872364; called by muse, mutect2, varscan2
- SYNE2 | c.18128C>G p.S6043C | Missense Mutation (SNP) | VAF 125/295 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV100646863; called by muse, mutect2, varscan2
- TAS2R7 | c.838A>G p.S280G | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99553606; called by muse, mutect2, varscan2
- TGM4 | c.1529T>G p.F510C | Missense Mutation (SNP) | VAF 100/179 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99942161; called by muse, mutect2, varscan2
- THAP3 | c.360G>C p.E120D (on ENST00000054650 / NM_001195753.1; = p.E127D on NM_138350.3) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as COSV99275471; called by muse, mutect2, varscan2
- TMPRSS11D | c.984G>T p.Q328H | Missense Mutation (SNP) | VAF 172/520 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV99384503; called by muse, mutect2, varscan2
- TMPRSS13 | c.1592G>A p.W531* | Nonsense Mutation (SNP) | VAF 52/99 reads (53%) | catalogued as rs1351101496, COSV101471377; called by muse, mutect2, varscan2
- TSHZ1 | c.3131G>A p.R1044Q (on ENST00000580243 / NM_001308210.2; = p.R999Q on NM_005786.6) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs557571956, COSV100433443; called by muse, mutect2, varscan2
- TTN | c.2231C>T p.A744V (on ENST00000591111; = p.A698V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/147 reads (10%) | PolyPhen benign (0.014); catalogued as COSV100597309; called by muse, mutect2
- UGT1A8 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 133/347 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.19); catalogued as rs267599267, COSV65078464; called by muse, mutect2, varscan2
- VAMP7 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 62/480 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as COSV52901516, COSV99387745; called by mutect2, varscan2
- WASF3 | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV100098209; called by muse, mutect2, varscan2
- ZFC3H1 | c.4705G>A p.V1569I | Missense Mutation (SNP) | VAF 57/63 reads (90%) | SIFT tolerated (0.35); PolyPhen benign (0.1); catalogued as rs769054073, COSV101110356; called by muse, mutect2, varscan2
- ZHX1 | c.2555C>G p.T852R | Missense Mutation (SNP) | VAF 482/874 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52878485; called by muse, mutect2, varscan2
- ZNF687 | c.2222A>G p.N741S | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.059); catalogued as rs781593158, COSV99649351; called by muse, mutect2, varscan2
- ZNF7 | c.436T>A p.F146I | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100295681; called by muse, mutect2, varscan2
- ZW10 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV99562485; called by muse, mutect2, varscan2
- CCDC171 | c.2733del p.K911Nfs*9 | Frame Shift Del (DEL) | VAF 28/137 reads (20%) | called by mutect2, pindel, varscan2
- FLNC | c.6329_6332del p.I2110Tfs*16 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- LHCGR | c.927_947+5del p.X309_splice | Splice Site (DEL) | VAF 18/78 reads (23%) | called by mutect2, pindel
- NUP205 | c.3196-12_3200del p.X1066_splice | Splice Site (DEL) | VAF 44/148 reads (30%) | called by mutect2, pindel
- PCBP2 | c.29_30delinsG p.L10* | Frame Shift Del (DEL) | VAF 57/281 reads (20%) | called by pindel, varscan2*
- BCL2L1 | c.240G>C p.V80= | Silent (SNP) | VAF 26/118 reads (22%) | called by mutect2, varscan2
- CHST15 | c.195C>T p.N65= | Silent (SNP) | VAF 53/106 reads (50%) | catalogued as rs760255628, COSV100654950; called by muse, mutect2, varscan2
- CIITA | c.2451G>A p.E817= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as COSV100161462; called by muse, mutect2, varscan2
- DEPDC5 | c.2037C>T p.T679= (on ENST00000400246; = p.T748= on NM_014662.5) | Silent (SNP) | VAF 96/115 reads (83%) | catalogued as rs373009424; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOLH1 | c.2112A>T p.S704= | Silent (SNP) | VAF 165/451 reads (37%) | catalogued as COSV99922778; called by muse, mutect2, varscan2
- FOXC1 | c.492C>T p.N164= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV101083231; called by muse, varscan2
- GP1BA | c.948C>G p.T316= | Silent (SNP) | VAF 146/176 reads (83%) | catalogued as COSV99850890; called by muse, mutect2, varscan2
- LDLR | c.1023C>T p.P341= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs376267007; called by muse, mutect2, varscan2
- LIMCH1 | c.843C>A p.P281= | Silent (SNP) | VAF 100/166 reads (60%) | catalogued as COSV100573447, COSV58297570; called by muse, mutect2, varscan2
- LNPEP | c.1332G>C p.L444= | Silent (SNP) | VAF 222/542 reads (41%) | catalogued as COSV99183483; called by muse, mutect2, varscan2
- LRP2 | c.12540T>A p.I4180= | Silent (SNP) | VAF 119/286 reads (42%) | catalogued as COSV99786794; called by muse, mutect2, varscan2
- LRRC7 | c.3357G>A p.P1119= (on ENST00000651989 / NM_001370785.2; = p.P1086= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs774965588, COSV99224841; called by muse, mutect2, varscan2
- NUP210L | c.57G>A p.L19= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99666097; called by muse, varscan2
- OR8K1 | c.414C>T p.Y138= | Silent (SNP) | VAF 211/484 reads (44%) | catalogued as rs757496734, COSV99687132, COSV99687376; called by muse, mutect2, varscan2
- PPARG | c.222T>C p.S74= (on ENST00000287820 / NM_015869.5; = p.S44= on NM_005037.7) | Silent (SNP) | VAF 167/374 reads (45%) | catalogued as COSV99826324; called by muse, mutect2, varscan2
- PRICKLE1 | c.375G>A p.V125= | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as COSV100566116; called by muse, mutect2, varscan2
- PTCHD4 | c.2406T>C p.I802= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV100260255; called by muse, mutect2, varscan2
- SLC5A6 | c.1236A>T p.G412= | Silent (SNP) | VAF 211/247 reads (85%) | catalogued as COSV100143076; called by muse, mutect2, varscan2
- SYNE3 | c.486C>T p.N162= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs751791161, COSV100515677; called by muse, mutect2, varscan2
- TBC1D4 | c.2202A>G p.Q734= | Silent (SNP) | VAF 19/209 reads (9%) | catalogued as COSV100884534; called by muse, mutect2
- ZNF519 | c.996C>A p.G332= | Silent (SNP) | VAF 386/647 reads (60%) | catalogued as COSV101645551, COSV73913296; called by muse, mutect2, varscan2
- ZSWIM5 | c.1191A>T p.T397= | Silent (SNP) | VAF 169/408 reads (41%) | catalogued as COSV100655367; called by muse, mutect2, varscan2
- PREX2 | c.2716-2965G>C | Intron (SNP) | VAF 16/480 reads (3%) | catalogued as COSV99905407; called by muse, mutect2
- SSX9P | n.219C>T | RNA (SNP) | VAF 24/500 reads (5%) | called by muse, mutect2
- STK4 | c.1306-21895G>C | Intron (SNP) | VAF 112/285 reads (39%) | catalogued as COSV100859921; called by muse, mutect2, varscan2
